Somatic mutation profile of tumor specimen C3N-01755-01 (aliquot CPT0163090006) from CPTAC case C3N-01755, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 68.1 years (24,868 days).
Specimen C3N-01755-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2115f87b-cbd3-4e0e-8aac-abe107c561dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01755-31 (Blood Derived Normal), aliquot CPT0163150002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a21cb907-d2f8-4ebd-8ce0-d8034dde0784

The open-access MAF lists 135 somatic variants for this specimen: 92 protein-altering or splice-affecting, 26 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 26, Nonsense Mutation 10, Frame Shift Del 6, Intron 6, 3'UTR 5, RNA 2, 5'UTR 2, Splice Site 2, Splice Region 2, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.430C>T p.Q144* | Nonsense Mutation (SNP) | VAF 101/231 reads (44%) | hotspot (GDC flag); catalogued as rs757274881, CM102352, COSV52662339, COSV52764890, COSV53424649; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS20 | c.1744C>A p.R582S | Missense Mutation (SNP) | VAF 91/325 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.043); catalogued as rs371102650; called by muse, mutect2, varscan2
- AGRN | c.2515G>A p.D839N | Missense Mutation (SNP) | VAF 42/302 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.495); catalogued as rs148315419; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP8B1 | c.3712G>A p.V1238M | Missense Mutation (SNP) | VAF 80/643 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.043); catalogued as rs1053938391, COSV52173001; called by muse, mutect2, varscan2
- CCDC39 | c.2155T>C p.S719P | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.202); catalogued as rs561979601; called by muse, mutect2, varscan2
- CLNK | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 53/283 reads (19%) | catalogued as rs776762622; called by muse, mutect2, varscan2
- COL1A2 | c.2776C>T p.R926C | Missense Mutation (SNP) | VAF 50/248 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745363291, COSV51967649, COSV99798007; called by muse, mutect2, varscan2
- COL5A1 | c.2896C>T p.P966S | Missense Mutation (SNP) | VAF 261/506 reads (52%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV65665309; called by muse, mutect2, varscan2
- CRCT1 | c.184T>A p.C62S | Missense Mutation (SNP) | VAF 100/408 reads (25%) | PolyPhen probably damaging (0.994); catalogued as COSV57500155; called by muse, mutect2
- CTR9 | c.2248G>A p.D750N | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.067); catalogued as COSV63727751, COSV63729685; called by muse, mutect2, varscan2
- ERICH1 | c.664G>A p.G222R | Missense Mutation (SNP) | VAF 106/313 reads (34%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs540464491; called by muse, mutect2, varscan2
- FAM47C | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT tolerated (0.63); PolyPhen benign (0.042); catalogued as rs782669806, COSV63730705; called by muse, mutect2, varscan2
- FLNA | c.4276G>A p.V1426I | Missense Mutation (SNP) | VAF 16/345 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.054); catalogued as rs782073521; called by muse, mutect2
- FSTL5 | c.1846G>A p.G616R | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV60198735; called by muse, varscan2
- GLCCI1 | c.1561C>T p.Q521* | Nonsense Mutation (SNP) | VAF 42/234 reads (18%) | catalogued as rs759542141; called by muse, mutect2, varscan2
- GNAS | c.140-4C>T | Splice Region (SNP) | VAF 46/337 reads (14%) | catalogued as rs1306389558; called by muse, mutect2, varscan2
- IGLON5 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 72/226 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774279745; called by muse, mutect2, varscan2
- KPTN | c.423C>G p.F141L | Missense Mutation (SNP) | VAF 33/471 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs927688047; called by muse, mutect2
- MAP7D2 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 76/159 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs752492865, COSV65530204; called by muse, mutect2, varscan2
- MGAT5B | c.2068C>T p.R690W (on ENST00000569840 / NM_001199172.2; = p.R688W on NM_144677.3) | Missense Mutation (SNP) | VAF 85/297 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as rs765459462, COSV56929505; called by muse, mutect2, varscan2
- MYH13 | c.2436G>A p.R812= | Splice Region (SNP) | VAF 57/201 reads (28%) | catalogued as COSV52823398; called by muse, mutect2, varscan2
- NGFR | c.1120G>C p.D374H | Missense Mutation (SNP) | VAF 113/425 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as COSV50802097; called by muse, mutect2, varscan2
- NOSIP | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 140/265 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV59199680; called by muse, mutect2, varscan2
- OPTC | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 332/696 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs762147346; called by muse, mutect2, varscan2
- PRDM6 | c.1405G>A p.D469N | Missense Mutation (SNP) | VAF 76/187 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68335722; called by muse, mutect2, varscan2
- SLC45A4 | c.470G>A p.G157D (on ENST00000517878 / NM_001286646.2; = p.G106D on NM_001080431.2) | Missense Mutation (SNP) | VAF 44/204 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs534295566; called by muse, mutect2, varscan2
- SLC4A3 | c.470del p.H157Pfs*113 | Frame Shift Del (DEL) | VAF 5/43 reads (12%) | catalogued as rs759883814, COSV56092392; called by pindel, varscan2
- SLC9A2 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 43/182 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs1558712761; called by muse, mutect2, varscan2
- SPINK9 | c.80A>C p.K27T | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV64958199; called by muse, mutect2
- TDRD6 | c.3430G>A p.D1144N | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.276); catalogued as rs1313166832; called by muse, mutect2, varscan2
- TMCC2 | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 203/540 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs767698690; called by muse, mutect2, varscan2
- TNS3 | c.2939A>G p.K980R | Missense Mutation (SNP) | VAF 100/524 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.026); catalogued as rs750282977; called by muse, mutect2
- TOGARAM2 | c.1898C>G p.S633* | Nonsense Mutation (SNP) | VAF 29/237 reads (12%) | catalogued as COSV101091509; called by muse, mutect2, varscan2
- TOPORS | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 26/201 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV62116690; called by muse, mutect2, varscan2
- TPTE | c.838C>T p.R280* (on ENST00000618007 / NM_199261.4; = p.R262* on NM_199259.4) | Nonsense Mutation (SNP) | VAF 20/242 reads (8%) | catalogued as rs755481692; called by muse, mutect2
- VPS33A | c.1083C>G p.I361M | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV99931196; called by muse, mutect2, varscan2
- WNT7B | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as rs144832567; called by muse, mutect2, varscan2
- ZNF180 | c.148C>G p.Q50E | Missense Mutation (SNP) | VAF 49/223 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.45); catalogued as COSV55419638, COSV55421868; called by muse, mutect2, varscan2
- ZNF341 | c.1726C>G p.P576A (on ENST00000375200 / NM_001282935.1; = p.P569A on NM_032819.4) | Missense Mutation (SNP) | VAF 107/607 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.251); catalogued as COSV100677753; called by muse, mutect2, varscan2
- AJUBA | c.1108+1G>A p.X370_splice | Splice Site (SNP) | VAF 16/45 reads (36%) | called by muse, mutect2, varscan2
- AP1G1 | c.197G>T p.G66V | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATP8B1 | c.2913C>A p.F971L | Missense Mutation (SNP) | VAF 29/265 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CACNG3 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 55/204 reads (27%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- CARD14 | c.1084G>A p.D362N | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CCDC102A | c.513_514del p.D172Rfs*13 | Frame Shift Del (DEL) | VAF 26/116 reads (22%) | called by pindel, varscan2
- CCNT2 | c.1084C>T p.Q362* | Nonsense Mutation (SNP) | VAF 23/177 reads (13%) | called by muse, mutect2, varscan2
- CEMIP2 | c.254G>T p.C85F | Missense Mutation (SNP) | VAF 67/110 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by mutect2, varscan2
- CHD2 | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CIT | c.3327G>T p.E1109D | Missense Mutation (SNP) | VAF 38/187 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CPLANE1 | c.7787C>T p.S2596L | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CPS1 | c.1708-1G>A p.X570_splice | Splice Site (SNP) | VAF 55/384 reads (14%) | called by muse, mutect2, varscan2
- CYP11B2 | c.99G>C p.R33S | Missense Mutation (SNP) | VAF 106/653 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DAPP1 | c.373C>A p.L125I | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DDX5 | c.1224A>T p.E408D | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- DNA2 | c.2315G>T p.C772F | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH10 | c.2142_2182del p.S715Tfs*8 (on ENST00000409039; = p.S654Tfs*8 on NM_207437.3) | Frame Shift Del (DEL) | VAF 34/222 reads (15%) | called by mutect2, pindel
- ENDOV | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 125/478 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ERBB4 | c.1878C>A p.N626K | Missense Mutation (SNP) | VAF 53/430 reads (12%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERICH3 | c.2918del p.A973Efs*16 | Frame Shift Del (DEL) | VAF 35/306 reads (11%) | called by mutect2, pindel, varscan2
- FAT1 | c.7193G>C p.R2398T | Missense Mutation (SNP) | VAF 45/199 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FYB2 | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 39/255 reads (15%) | called by muse, mutect2, varscan2
- GORAB | c.369G>C p.E123D | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HNF1B | c.263C>A p.T88K | Missense Mutation (SNP) | VAF 82/315 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- HNRNPR | c.1487G>A p.G496D | Missense Mutation (SNP) | VAF 34/275 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- ICMT | c.178C>G p.R60G | Missense Mutation (SNP) | VAF 37/348 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.433); called by mutect2, varscan2
- IFNA7 | c.322T>G p.F108V | Missense Mutation (SNP) | VAF 229/496 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- KCNJ3 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 53/199 reads (27%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- KPRP | c.586C>T p.Q196* | Nonsense Mutation (SNP) | VAF 62/405 reads (15%) | called by muse, mutect2, varscan2
- KRR1 | c.106G>A p.V36I | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- MAPKAPK3 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- MMS22L | c.2199del p.V734Cfs*16 | Frame Shift Del (DEL) | VAF 35/227 reads (15%) | called by mutect2, pindel, varscan2
- MYLK | c.3230G>A p.C1077Y | Missense Mutation (SNP) | VAF 55/489 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PARD6G | c.181A>C p.T61P | Missense Mutation (SNP) | VAF 56/368 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- PLPP1 | c.14C>G p.T5R | Missense Mutation (SNP) | VAF 126/337 reads (37%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRDM15 | c.973A>T p.T325S | Missense Mutation (SNP) | VAF 129/390 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRELID3B | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 40/218 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- S100PBP | c.206A>T p.Y69F | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- SCLY | c.1118G>A p.G373E (on ENST00000651534; = p.G365E on NM_016510.7) | Missense Mutation (SNP) | VAF 30/195 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEC14L1 | c.193G>T p.A65S | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- SENP3 | c.288G>C p.W96C | Missense Mutation (SNP) | VAF 99/309 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- SLAMF9 | c.180T>G p.S60R | Missense Mutation (SNP) | VAF 13/260 reads (5%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2
- SLC8A1 | c.976A>G p.M326V | Missense Mutation (SNP) | VAF 55/322 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SLIT1 | c.4318del p.A1440Hfs*64 | Frame Shift Del (DEL) | VAF 11/93 reads (12%) | called by mutect2, pindel
- SMARCA4 | c.196C>T p.Q66* | Nonsense Mutation (SNP) | VAF 84/271 reads (31%) | called by muse, mutect2, varscan2
- TMEM161B | c.163C>A p.Q55K | Missense Mutation (SNP) | VAF 56/153 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- TRAM1 | c.1027G>T p.G343C | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- WSB1 | c.272G>A p.S91N | Missense Mutation (SNP) | VAF 56/252 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- YTHDC1 | c.1659T>A p.Y553* (on ENST00000344157 / NM_001031732.4; = p.Y535* on NM_133370.4) | Nonsense Mutation (SNP) | VAF 30/130 reads (23%) | called by muse, mutect2, varscan2
- ZHX1 | c.1055G>A p.R352K | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- ZNF181 | c.271_273del p.K91del | In Frame Del (DEL) | VAF 22/50 reads (44%) | called by pindel, varscan2
- ZNF518A | c.386G>T p.R129L | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ZNF749 | c.1993G>A p.E665K | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- ALKAL2 | c.393T>C p.Y131= | Silent (SNP) | VAF 60/259 reads (23%) | catalogued as rs775186424, COSV55245789; called by muse, mutect2, varscan2
- ALX4 | c.153C>A p.A51= | Silent (SNP) | VAF 171/723 reads (24%) | called by muse, mutect2, varscan2
- BRCA2 | c.138T>C p.P46= | Silent (SNP) | VAF 39/151 reads (26%) | called by muse, mutect2, varscan2
- COMMD8 | c.270C>A p.I90= | Silent (SNP) | VAF 30/144 reads (21%) | called by muse, mutect2, varscan2
- DNAH2 | c.2250C>T p.T750= | Silent (SNP) | VAF 53/226 reads (23%) | catalogued as COSV101209386; called by muse, mutect2, varscan2
- DST | c.13653G>A p.V4551= (on ENST00000361203 / NM_001374722.1; = p.V2139= on NM_015548.5) | Silent (SNP) | VAF 15/114 reads (13%) | called by muse, varscan2
- DUSP8 | c.378C>T p.F126= | Silent (SNP) | VAF 38/170 reads (22%) | catalogued as rs1484722275; called by muse, mutect2, varscan2
- HECW2 | c.3705C>G p.G1235= | Silent (SNP) | VAF 9/96 reads (9%) | called by muse, mutect2, varscan2
- JAG1 | c.3651C>T p.I1217= | Silent (SNP) | VAF 62/362 reads (17%) | catalogued as rs542831744, COSV54752845; ClinVar: benign / uncertain significance / likely benign; called by muse, mutect2, varscan2
- LRP1B | c.7857T>G p.A2619= | Silent (SNP) | VAF 24/112 reads (21%) | called by muse, mutect2, varscan2
- MAGEA11 | c.1167G>A p.R389= | Silent (SNP) | VAF 50/127 reads (39%) | called by muse, mutect2, varscan2
- MLF1 | c.360G>A p.P120= | Silent (SNP) | VAF 15/213 reads (7%) | catalogued as rs774704786, COSV63033727; called by muse, mutect2
- NALCN | c.2805G>A p.L935= | Silent (SNP) | VAF 12/99 reads (12%) | called by muse, mutect2, varscan2
- OASL | c.1281G>A p.L427= | Silent (SNP) | VAF 38/146 reads (26%) | catalogued as COSV56566333; called by muse, mutect2, varscan2
- OR10C1 | c.195C>A p.R65= (on ENST00000622521; = p.R63= on NM_013941.3) | Silent (SNP) | VAF 57/213 reads (27%) | called by muse, mutect2, varscan2
- PCDHB5 | c.1980C>T p.L660= | Silent (SNP) | VAF 263/588 reads (45%) | called by muse, mutect2, varscan2
- PJA1 | c.543G>A p.K181= | Silent (SNP) | VAF 40/89 reads (45%) | called by muse, mutect2, varscan2
- PKD1L3 | c.1632C>A p.S544= | Silent (SNP) | VAF 21/196 reads (11%) | called by muse, varscan2
- PLSCR3 | c.786G>C p.L262= | Silent (SNP) | VAF 47/285 reads (16%) | catalogued as rs773115794; called by muse, mutect2, varscan2
- SLC28A3 | c.1356G>A p.V452= | Silent (SNP) | VAF 39/268 reads (15%) | called by muse, mutect2, varscan2
- TBL3 | c.1668C>A p.L556= | Silent (SNP) | VAF 51/236 reads (22%) | called by muse, mutect2, varscan2
- TCF7L1 | c.1566C>T p.F522= | Silent (SNP) | VAF 48/241 reads (20%) | catalogued as rs777271008; called by muse, mutect2, varscan2
- TCHH | c.2760G>A p.K920= | Silent (SNP) | VAF 92/376 reads (24%) | catalogued as COSV100914851; called by muse, mutect2, varscan2
- TG | c.4332C>T p.F1444= | Silent (SNP) | VAF 54/366 reads (15%) | called by muse, mutect2, varscan2
- UBN1 | c.1746G>A p.L582= | Silent (SNP) | VAF 56/253 reads (22%) | called by muse, mutect2, varscan2
- ZNF596 | c.297C>T p.I99= | Silent (SNP) | VAF 20/145 reads (14%) | called by muse, mutect2, varscan2
- AC006486.1 | c.23-3068C>T | Intron (SNP) | VAF 74/342 reads (22%) | catalogued as rs547169672; called by mutect2, varscan2
- AC022415.2 | c.*2182G>A | 3'UTR (SNP) | VAF 43/136 reads (32%) | called by muse, mutect2, varscan2
- AL583829.1 | n.468+7378G>A | Intron (SNP) | VAF 25/294 reads (9%) | called by muse, mutect2
- BBS5 | c.-4C>T | 5'UTR (SNP) | VAF 55/360 reads (15%) | called by muse, mutect2, varscan2
- CD320 | c.*115G>T | 3'UTR (SNP) | VAF 143/455 reads (31%) | called by muse, mutect2, varscan2
- CHIT1 | c.*605G>A | 3'UTR (SNP) | VAF 55/536 reads (10%) | called by muse, mutect2, varscan2
- CLN5 | chr13:76992020 C>G | 5'Flank (SNP) | VAF 153/496 reads (31%) | catalogued as COSV101080461; called by muse, mutect2, varscan2
- GSDMD | c.411-261G>A | Intron (SNP) | VAF 12/58 reads (21%) | called by muse, mutect2, varscan2
- KLF6 | c.*2003G>A | 3'UTR (SNP) | VAF 70/257 reads (27%) | called by muse, mutect2, varscan2
- LINC01556 | n.92G>A | RNA (SNP) | VAF 14/39 reads (36%) | called by muse, mutect2, varscan2
- MAF1 | c.*123C>G | 3'UTR (SNP) | VAF 22/116 reads (19%) | called by muse, mutect2
- OR2L1P | n.777G>T | RNA (SNP) | VAF 187/378 reads (49%) | called by muse, mutect2, varscan2
- PIM1 | c.-89C>A | 5'UTR (SNP) | VAF 169/541 reads (31%) | called by muse, mutect2, varscan2
- PNCK | c.69-92C>T | Intron (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- PRND | chr20:4732579 G>A | 3'Flank (SNP) | VAF 71/434 reads (16%) | called by muse, mutect2, varscan2
- SPOCK3 | c.245-10832C>T | Intron (SNP) | VAF 20/138 reads (14%) | called by muse, mutect2, varscan2
- TRIM5 | c.895+106A>G | Intron (SNP) | VAF 9/29 reads (31%) | catalogued as rs373332285; called by muse, mutect2, varscan2
